Somatic mutation profile of tumor specimen MP2PRT-PAVMPD-TMP1-A (aliquot MP2PRT-PAVMPD-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVMPD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.7 years (3,182 days).
Specimen MP2PRT-PAVMPD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 478ae115-daff-44c2-ac81-1c333078724b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVMPD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVMPD-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6096afd7-20cd-4a38-af1a-07d6c10b671a

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Frame Shift Ins 1, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 36/103 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- EHBP1L1 | c.4556G>A p.R1519H | Missense Mutation (SNP) | VAF 17/559 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1433387329; called by muse, mutect2
- GPR50 | c.1328C>A p.S443Y | Missense Mutation (SNP) | VAF 330/380 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV99505476; called by muse, mutect2, varscan2
- MET | c.1363C>A p.L455I | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780077898, COSV59265757; called by muse, mutect2, varscan2
- MYH1 | c.3388C>T p.R1130W | Missense Mutation (SNP) | VAF 126/389 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56844359; called by muse, mutect2, varscan2
- RP1 | c.872A>C p.Q291P | Missense Mutation (SNP) | VAF 103/237 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs768361590; called by muse, mutect2, varscan2
- SIGLEC15 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 31/832 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs886459560; called by muse, mutect2
- SLC27A1 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 32/660 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770565930, COSV99393770; called by muse, mutect2
- BRINP2 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 114/393 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FANCM | c.4413_4414del p.S1471Rfs*17 | Frame Shift Del (DEL) | VAF 47/138 reads (34%) | called by mutect2, pindel, varscan2
- MYT1 | c.1146G>T p.E382D | Missense Mutation (SNP) | VAF 275/737 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PWWP3A | c.2010_2011insCGACGAGGA p.R670_A671insRRG (on ENST00000627377; = p.R669_A670insRRG on NM_001369794.1) | In Frame Ins (INS) | VAF 105/358 reads (29%) | called by mutect2, pindel*, varscan2*
- TAS1R1 | c.574_575insTC p.D192Vfs*33 | Frame Shift Ins (INS) | VAF 175/510 reads (34%) | called by mutect2, pindel, varscan2
- IGLV3-27 | c.288C>T p.A96= | Silent (SNP) | VAF 112/263 reads (43%) | called by muse, mutect2, varscan2
- KIRREL3 | c.393G>A p.Q131= | Silent (SNP) | VAF 92/594 reads (15%) | called by muse, mutect2
- MMRN2 | c.1683G>A p.T561= | Silent (SNP) | VAF 58/842 reads (7%) | called by muse, mutect2
- NMNAT2 | c.342C>A p.L114= | Silent (SNP) | VAF 30/299 reads (10%) | called by muse, mutect2, varscan2
